Somatic mutation profile of tumor specimen ALCH-B0HC-TTP1-A (aliquot ALCH-B0HC-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B0HC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.1 years (22,302 days).
Specimen ALCH-B0HC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 127ce60a-396d-4fc8-92b9-a8d5f77b642d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0HC-NB1-A (Blood Derived Normal), aliquot ALCH-B0HC-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/534d4ac9-6fbf-4ab4-9305-d4e47a98b830

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Intron 2, 5'UTR 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 29/380 reads (8%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV52517971, COSV52518546; called by muse, mutect2
- CARS2 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1263877433, COSV57288148; called by muse, mutect2, varscan2
- DYSF | c.5398C>T p.P1800S | Missense Mutation (SNP) | VAF 51/580 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246530144; called by muse, mutect2
- EP300 | c.5603C>T p.T1868M | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs781609478; called by muse, mutect2
- FKBPL | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403764557; called by muse, mutect2
- JPH3 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 29/376 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs375292901; called by muse, mutect2
- LRP3 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1443288621, COSV53503311; called by muse, mutect2
- NFATC4 | c.962del p.P321Hfs*99 | Frame Shift Del (DEL) | VAF 18/121 reads (15%) | catalogued as COSV51611271; called by mutect2, pindel, varscan2
- OR1Q1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 26/375 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs775441414, COSV52917886; called by muse, mutect2
- PCDHB15 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 62/954 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as rs1196022829; called by muse, mutect2
- PTPRS | c.5389G>A p.E1797K | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1420539666; called by muse, mutect2
- RIC1 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV52610088; called by muse, mutect2
- SCIN | c.823G>A p.A275T (on ENST00000297029 / NM_001112706.3; = p.A28T on NM_033128.3) | Missense Mutation (SNP) | VAF 59/607 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1379619043; called by muse, mutect2, varscan2
- ZGRF1 | c.5147T>G p.F1716C | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421512090; called by muse, mutect2
- ZNF831 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1409992503; called by muse, mutect2, varscan2
- ZNF850 | c.1309A>C p.I437L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.472); catalogued as rs879140289; called by muse, mutect2
- ATP13A2 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CNDP1 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- DYNC2LI1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.076); called by muse, mutect2
- KCNE5 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- KIAA1109 | c.6525G>A p.M2175I | Missense Mutation (SNP) | VAF 39/628 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- MIA3 | c.3661A>C p.K1221Q | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2
- NUP210 | c.1001G>C p.R334T | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.738); called by muse, mutect2
- PACC1 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA2 | c.1425C>G p.F475L | Missense Mutation (SNP) | VAF 58/770 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.762); called by muse, mutect2
- PKN2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- PKNOX1 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2
- SCML1 | c.746G>A p.G249E (on ENST00000380041 / NM_001037540.3; = p.G222E on NM_006746.6) | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3B | c.1115T>G p.V372G | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- SLC25A12 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- SLC9A2 | c.1070C>G p.T357R | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMARCE1 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- TACC2 | c.5239C>G p.Q1747E | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.071); called by muse, mutect2
- TLX2 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.005); called by muse, mutect2
- WDR49 | c.1719T>G p.N573K (on ENST00000308378 / NM_001366158.1; = p.N914K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- ZFAT | c.3576G>C p.Q1192H | Missense Mutation (SNP) | VAF 25/388 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ZNF135 | c.783G>C p.Q261H (on ENST00000313434 / NM_001289401.2; = p.Q273H on NM_003436.4) | Missense Mutation (SNP) | VAF 42/475 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); called by muse, mutect2
- ARRDC5 | c.594C>T p.T198= (on ENST00000381781; = p.T184= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/510 reads (10%) | catalogued as COSV67788337; called by muse, mutect2
- BFSP2 | c.1167G>C p.A389= | Silent (SNP) | VAF 39/593 reads (7%) | catalogued as rs1363263240, COSV56587926; called by muse, mutect2
- C19orf84 | c.510G>A p.E170= | Silent (SNP) | VAF 54/564 reads (10%) | called by muse, mutect2
- CYP2A6 | c.864G>A p.L288= | Silent (SNP) | VAF 28/324 reads (9%) | called by muse, mutect2
- DTWD2 | c.141G>A p.A47= | Silent (SNP) | VAF 23/261 reads (9%) | catalogued as rs1349704513; called by muse, mutect2
- FAAP24 | c.561G>A p.L187= | Silent (SNP) | VAF 34/494 reads (7%) | catalogued as COSV54274921, COSV54286537; called by muse, mutect2
- HDHD3 | c.285C>T p.A95= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.261T>C p.S87= | Silent (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- RCOR2 | c.705C>T p.R235= | Silent (SNP) | VAF 24/302 reads (8%) | catalogued as rs1189831075; called by muse, mutect2
- TANC1 | c.3675G>A p.E1225= | Silent (SNP) | VAF 25/290 reads (9%) | called by muse, mutect2
- FAM120AOS | c.685-789G>C | Intron (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- KLK9 | c.-28C>T | 5'UTR (SNP) | VAF 15/178 reads (8%) | catalogued as rs765799306; called by muse, mutect2
- RECQL5 | c.*242G>A | 3'UTR (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1915+549G>A | Intron (SNP) | VAF 20/254 reads (8%) | catalogued as rs1267835409, COSV60496033; called by muse, mutect2
- STMP1 | c.-61C>G | 5'UTR (SNP) | VAF 14/140 reads (10%) | called by muse, varscan2
